Somatic mutation profile of tumor specimen MMRF_1312_1_BM_CD138pos (aliquot MMRF_1312_1_BM_CD138pos_T1_KAS5U_L00342) from MMRF case MMRF_1312, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.2 years (25,648 days).
Specimen MMRF_1312_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8e52124-17c4-4725-b878-f6efffd4c7bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1312_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1312_1_PB_Whole_C2_KAS5U_L00343; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1aa5b01-c374-4bf9-a7bb-2b4f1857fd91

The open-access MAF lists 122 somatic variants for this specimen: 47 protein-altering or splice-affecting, 25 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 25, 3'UTR 24, Intron 18, 5'UTR 5, Frame Shift Ins 2, In Frame Del 2, RNA 1, Splice Region 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 4/37 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 16/87 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTG2 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.23); catalogued as rs1553394796, COSV61830035; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRL4 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV66059653; called by muse, mutect2, varscan2
- C6orf118 | c.254G>T p.R85L | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as COSV100024685; called by muse, mutect2, varscan2
- CMYA5 | c.8335A>G p.K2779E | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV71406746; called by muse, mutect2
- CYP21A2 | c.1099C>A p.R367S | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.672); catalogued as rs758658540, CM1210497, COSV64475730; called by muse, mutect2
- H1-3 | c.241A>C p.I81L | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as COSV55097171; called by muse, mutect2, varscan2
- HECW1 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.055); catalogued as rs1413143821, COSV67828516; called by muse, mutect2, varscan2
- IRX1 | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs949207066; called by muse, mutect2, varscan2
- KLHL11 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV59861539, COSV59861587; called by muse, mutect2, varscan2
- LRRC56 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as rs753597038, COSV54245730; called by muse, mutect2, varscan2
- LRRN4 | c.727A>C p.T243P | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.177); catalogued as COSV66644606; called by muse, varscan2
- MAN1A1 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as rs759889486; called by muse, mutect2, varscan2
- MICALL1 | c.878T>C p.L293P | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs1443291718; called by muse, mutect2, varscan2
- MYH8 | c.4726G>A p.D1576N | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.182); catalogued as COSV67969425; called by muse, mutect2
- NANOGNB | c.423G>A p.M141I | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.359); catalogued as rs1565471700; called by muse, mutect2, varscan2
- SEMA3F | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 17/319 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs372829300, COSV50029313; called by muse, mutect2
- SORL1 | c.5892G>C p.L1964F | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV52755280; called by muse, mutect2, varscan2
- SPTBN4 | c.5347C>G p.R1783G | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58948161; called by muse, mutect2, varscan2
- UBR4 | c.9794A>G p.Q3265R | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.838); catalogued as rs1253378001; called by muse, mutect2, varscan2
- AMIGO3 | c.1234_1254del p.R412_R418del | In Frame Del (DEL) | VAF 40/148 reads (27%) | called by mutect2, pindel, varscan2
- ANKHD1-EIF4EBP3 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2
- CACNA1D | c.719_728delinsTCCGCCT p.R240_R243delinsLRL | In Frame Del (DEL) | VAF 16/30 reads (53%) | called by pindel, varscan2*
- CCPG1 | c.409G>A p.G137S | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); called by muse, mutect2
- DNTT | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GMCL2 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); called by muse, mutect2
- H1-3 | c.439A>T p.T147S | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.95); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- H1-3 | c.332A>G p.K111R | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HNRNPUL1 | c.1418A>G p.Y473C | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- KCNC3 | c.910A>T p.I304F | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- KRTAP1-3 | c.170G>A p.S57N | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.009); called by muse, varscan2
- LGR5 | c.2466G>C p.L822F | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MAX | c.296-5T>G | Splice Region (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- OVCH2 | c.860T>A p.I287N | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- RBM10 | c.1091A>C p.Q364P | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- RNF133 | c.146G>C p.G49A | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- RSBN1 | c.566dup p.E190Gfs*14 | Frame Shift Ins (INS) | VAF 66/150 reads (44%) | called by mutect2, pindel, varscan2
- RTN1 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.057); called by muse, mutect2
- SOX11 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STK32A | c.36T>G p.F12L | Missense Mutation (SNP) | VAF 13/240 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- TTC23 | c.647T>G p.V216G | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- UBR5 | c.6474dup p.T2159Yfs*2 | Frame Shift Ins (INS) | VAF 25/57 reads (44%) | called by mutect2, pindel, varscan2
- UTP3 | c.869T>A p.V290D | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- VMP1 | c.1110G>C p.K370N | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- VSTM2B | c.586G>A p.G196S | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- XKR7 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.84); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AGK | c.819T>A p.P273= | Silent (SNP) | VAF 33/79 reads (42%) | called by muse, mutect2, varscan2
- CDH23 | c.9594T>A p.I3198= | Silent (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- CDHR1 | c.618C>T p.H206= | Silent (SNP) | VAF 42/88 reads (48%) | called by muse, mutect2, varscan2
- CHURC1 | c.312C>T p.I104= (on ENST00000549115 / NM_001204063.1; = p.I105= on NM_145165.3) | Silent (SNP) | VAF 13/22 reads (59%) | called by muse, mutect2, varscan2
- CTSL | c.1001G>A p.*334= | Silent (SNP) | VAF 27/103 reads (26%) | called by muse, mutect2, varscan2
- EN1 | c.87G>A p.L29= | Silent (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- GABRG2 | c.321C>A p.I107= | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- ILDR2 | c.810T>C p.S270= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- KCNA4 | c.813G>A p.E271= | Silent (SNP) | VAF 12/115 reads (10%) | called by muse, mutect2
- KCTD7 | c.747T>C p.S249= (on ENST00000275532; = p.C263R on NM_153033.5) | Silent (SNP) | VAF 9/169 reads (5%) | called by muse, mutect2
- MED16 | c.636C>T p.R212= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as rs754094568; called by muse, mutect2, varscan2
- MKI67 | c.7590G>A p.K2530= | Silent (SNP) | VAF 37/83 reads (45%) | called by muse, mutect2, varscan2
- MNT | c.1338C>T p.T446= | Silent (SNP) | VAF 36/65 reads (55%) | called by muse, mutect2, varscan2
- NKRF | c.2049G>A p.E683= | Silent (SNP) | VAF 5/138 reads (4%) | called by muse, mutect2
- NLGN4Y | c.1053C>T p.D351= | Silent (SNP) | VAF 37/43 reads (86%) | called by muse, mutect2, varscan2
- OBSL1 | c.2637C>T p.C879= | Silent (SNP) | VAF 20/179 reads (11%) | catalogued as rs191852351; ClinVar: likely benign; called by muse, mutect2, varscan2
- PAPLN | c.885C>T p.Y295= (on ENST00000554301; = p.Y268= on NM_173462.4) | Silent (SNP) | VAF 36/40 reads (90%) | called by muse, mutect2, varscan2
- S1PR4 | c.1104C>T p.S368= | Silent (SNP) | VAF 70/133 reads (53%) | called by muse, mutect2, varscan2
- SERPINA12 | c.1095G>A p.T365= | Silent (SNP) | VAF 28/30 reads (93%) | catalogued as rs1280744067; called by mutect2, varscan2
- SLCO4C1 | c.1563A>G p.Q521= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs148072603; called by muse, mutect2, varscan2
- TAF5 | c.1689G>A p.E563= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs905735165; called by muse, mutect2, varscan2
- VWF | c.1059C>T p.S353= | Silent (SNP) | VAF 33/70 reads (47%) | catalogued as rs767726061; called by muse, mutect2, varscan2
- ZHX2 | c.2037C>T p.N679= | Silent (SNP) | VAF 53/132 reads (40%) | called by muse, mutect2, varscan2
- ZNF286A | c.153C>A p.A51= | Silent (SNP) | VAF 13/120 reads (11%) | called by muse, mutect2, varscan2
- ZNF648 | c.549C>T p.S183= | Silent (SNP) | VAF 39/60 reads (65%) | catalogued as COSV60570243, COSV60571875; called by muse, mutect2, varscan2
- AMER3 | c.*1038G>C | 3'UTR (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2
- CCIN | c.*2C>T | 3'UTR (SNP) | VAF 18/199 reads (9%) | catalogued as rs749962330; called by muse, mutect2
- CCPG1 | c.-6T>A | 5'UTR (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2
- CD37 | c.69+19A>T | Intron (SNP) | VAF 22/264 reads (8%) | called by muse, mutect2
- CDH7 | chr18:65881819 C>G | 3'Flank (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- CFAP91 | c.1680+19del | Intron (DEL) | VAF 19/67 reads (28%) | called by mutect2, pindel, varscan2
- CITED4 | c.*50G>A | 3'UTR (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- CTNND2 | c.3343+1383C>T | Intron (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- EFR3B | c.2142+956A>C | Intron (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- EIF4E | c.*1544A>G | 3'UTR (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2, varscan2
- FAU | c.220+91G>A | Intron (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- FGA | c.*996C>A | 3'UTR (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- FNTB | c.-30T>G | 5'UTR (SNP) | VAF 30/95 reads (32%) | catalogued as rs201739947; called by muse, varscan2
- GBF1 | c.3507-18dup | Intron (INS) | VAF 21/60 reads (35%) | called by mutect2, pindel, varscan2
- GCOM2 | n.1051G>T | RNA (SNP) | VAF 11/96 reads (11%) | called by muse, mutect2, varscan2
- GGPS1 | c.*1370G>A | 3'UTR (SNP) | VAF 18/26 reads (69%) | called by muse, mutect2, varscan2
- GMPS | c.*547A>G | 3'UTR (SNP) | VAF 18/100 reads (18%) | called by muse, mutect2, varscan2
- GRID2 | c.-260A>C | 5'UTR (SNP) | VAF 25/58 reads (43%) | called by muse, mutect2, varscan2
- GTF3C4 | c.*2053C>T | 3'UTR (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- KALRN | c.7193+410T>A | Intron (SNP) | VAF 28/82 reads (34%) | catalogued as rs1382653913; called by muse, varscan2
- KCNT2 | c.*1277G>A | 3'UTR (SNP) | VAF 52/53 reads (98%) | catalogued as rs1018373056, COSV54064549; called by muse, mutect2, varscan2
- KRTAP9-7 | c.*447T>A | 3'UTR (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- LDHAL6A | c.-475C>T | 5'UTR (SNP) | VAF 10/188 reads (5%) | catalogued as rs902558536, COSV55006277; called by muse, mutect2
- LIN7C | c.*983A>T | 3'UTR (SNP) | VAF 38/110 reads (35%) | called by muse, mutect2, varscan2
- NAV3 | c.*532A>C | 3'UTR (SNP) | VAF 15/29 reads (52%) | called by muse, mutect2, varscan2
- NFIB | c.*4558G>C | 3'UTR (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- NOS1AP | c.*1962T>A | 3'UTR (SNP) | VAF 17/73 reads (23%) | called by muse, mutect2, varscan2
- PBX2 | c.*716G>C | 3'UTR (SNP) | VAF 64/110 reads (58%) | called by muse, mutect2, varscan2
- PDZRN3 | c.919-29244G>A | Intron (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2, varscan2
- PLPPR2 | c.*316C>G | 3'UTR (SNP) | VAF 15/247 reads (6%) | catalogued as COSV99264289; called by muse, mutect2
- PML | c.1710+1519A>G | Intron (SNP) | VAF 16/418 reads (4%) | called by muse, mutect2
- PRKCSH | chr19:11435615 G>C | 5'Flank (SNP) | VAF 3/37 reads (8%) | catalogued as rs1057359553; called by muse, mutect2
- PROM2 | c.976-52C>G | Intron (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2, varscan2
- PSMA1 | c.*186dup | 3'UTR (INS) | VAF 43/139 reads (31%) | called by mutect2, pindel, varscan2
- PSMG4 | c.250+382G>A | Intron (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- PTPRQ | c.5913-127T>C | Intron (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- S1PR2 | c.-43+747C>T | Intron (SNP) | VAF 25/75 reads (33%) | called by muse, mutect2, varscan2
- SAMD4A | c.*970A>G | 3'UTR (SNP) | VAF 27/58 reads (47%) | catalogued as rs1161106334; called by muse, mutect2, varscan2
- SCN8A | c.*337G>T | 3'UTR (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- SESN1 | c.-372C>T | 5'UTR (SNP) | VAF 38/82 reads (46%) | called by muse, mutect2, varscan2
- SFXN5 | c.*1242C>G | 3'UTR (SNP) | VAF 41/93 reads (44%) | called by muse, mutect2, varscan2
- SLC25A48 | c.813+1127G>C | Intron (SNP) | VAF 53/212 reads (25%) | called by muse, mutect2, varscan2
- TJP2 | c.3322-124C>T | Intron (SNP) | VAF 4/63 reads (6%) | called by muse, mutect2
- TMEM213 | c.*1789A>G | 3'UTR (SNP) | VAF 5/49 reads (10%) | catalogued as rs1011187760; called by muse, mutect2
- UCK1 | c.*1003G>A | 3'UTR (SNP) | VAF 36/117 reads (31%) | called by muse, mutect2, varscan2
- UNC50 | c.-4-242T>A | Intron (SNP) | VAF 28/59 reads (47%) | called by muse, mutect2, varscan2
- USF3 | c.*5558T>C | 3'UTR (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- USP45 | c.*1252C>T | 3'UTR (SNP) | VAF 4/83 reads (5%) | called by muse, mutect2
- XKR6 | c.764+62572G>A | Intron (SNP) | VAF 41/45 reads (91%) | called by muse, mutect2, varscan2
- YIF1A | c.427+93T>A | Intron (SNP) | VAF 26/208 reads (13%) | called by muse, mutect2, varscan2
